Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A83I, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A83I-01A (Primary Tumor).

[page 1 of 5]
Name
Encounter NumberGender
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
StatusTime Received
Order Number

Results

Final

Source of Specimen

- A. RIGHT OBTURATOR LYMPH NODE-FS-
- B. RIGHT OBTURATOR LYMPH NODE-NFS-
- C. LEFT OBTURATOR LYMPH NODE-FS-
- D. LEFT OBTURATOR LYMPH NODE-NFS-
- E. ? BLADDER NECK -FS-
- F. PROSTATE, SEMINAL VESICLES, VAS DEFERENS-

FINAL DIAGNOSIS:

- A. RIGHT OBTURATOR LYMPH NODE-FS-
SEE PART "B" FOR DIAGNOSIS.
- B. RIGHT OBTURATOR LYMPH NODE-NFS-
FRAGMENTS OF LYMPH NODE, NEGATIVE FOR TUMOR.
- C. LEFT OBTURATOR LYMPH NODE-FS-
SEE PART "D" FOR DIAGNOSIS.
- D. LEFT OBTURATOR LYMPH NODE-NFS-
FRAGMENTS OF LYMPH NODE, NEGATIVE FOR TUMOR.
- E. ? BLADDER NECK -FS-
FIBROMUSCULAR TISSUE AND URETHRA, NEGATIVE FOR TUMOR.
- F. PROSTATE, SEMINAL VESICLES, VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE WITH FOCAL MICROSCOPIC EXTENSION INTO
RIGHT EXTRAPROSTATIC SOFT TISSUE.

TUMOR SITE: RIGHT AND LEFT PROSTATE, MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 20 GRAMS. SIZE: 3 x 3 x 2.5 CM.

ICD-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Prostate NOS C61.9

[page 2 of 5]
GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 4 + 3 = 7/10.

TERTIARY PATTERN: NOT SEEN.

SEVERITY IN EXTENT OF TUMOR: 4/5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): IS PRESENT, AT LEAST 1.8 CM IN SIZE.

TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: pT3a, pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT MARGINS OF PROSTATE, SOFT TISSUE, URETHRA AND BLADDER NECK.

[REDACTED]

Signed Others

Frozen Section

A. RIGHT OBTURATOR LYMPH NODE: ONE FATTY LYMPH NODE. NO CARCINOMA SEEN (0/1).

LEFT OBTURATOR LYMPH NODE: ONE FATTY LYMPH NODE. NO CARCINOMA SEEN (0/1).

? BLADDER NECK: MUSCULAR TISSUE WITH SCANT PROSTATIC GLANDS. NO TUMOR SEEN.

Frozen section performed by [REDACTED]

[REDACTED]

Case Clinical Information

ADENOCARCINOMA OF THE PROSTATE

[REDACTED]

[page 3 of 5]
Gross Description

- A. Received in formalin labeled with the patient's name and "right obturator lymph node FS" are three gray-tan, fibrofatty FS tissue fragments. The largest measures 1.4 x 1 cm. The smallest measures 1.2 x 0.4 cm. Submitted complete in A1.
- B. Received in formalin labeled with the patient's name and "right obturator lymph nodes NFS" is a yellow, fibrofatty tissue fragment measuring 4 x 3 cm. The fat is trimmed and three probable lymph nodes are grossly identified. The largest measures 1 x 1 cm and the smallest measures 0.7 x 0.2 cm. The specimen is submitted complete in B1.
- C. Received in formalin labeled with the patient's name and "left obturator lymph nodes FS" are three yellow, fibrofatty FS tissue fragments. The largest measures 1.3 x 0.6 cm and the smallest measures 0.7 x 0.4 cm. Submitted complete in C1.
- D. Received in formalin labeled with the patient's name and "left obturator lymph nodes NFS" is a yellow, fibrofatty tissue fragment measuring 3 x 2 cm. The fat is trimmed and three probable lymph nodes are grossly identified. The largest measures 2 x 1 x 0.2 cm. The smallest measures 0.5 x 0.4 cm. Submitted complete in D1.
- E. Received in formalin labeled with the patient's name and "bladder neck FS" is a gray-tan, fibrous FS tissue fragment measuring 1.5 x 1 cm. Submitted complete in E1.
- F. Received in formalin labeled with the patient's name and "prostate, seminal vesicles, and vas deferens" is a radical prostatectomy specimen which includes a 20-gram prostate gland with attached seminal vesicle and vas deferens. The prostate gland measures 3 x 3 x 2.5 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 2 x 1.5 cm. The right vas deferens measures 2 x 0.5 cm. The left seminal vesicle measures 2 x 1.5 cm. The left vas deferens measures 2 x 0.5 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen, and sectioned from anterior to posterior parallel to the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. Representative sections submitted as follows: inferior prostate to demonstrate apical margin submitted entirely anterior to posterior in F1-F6; bladder resection margin shaved, serially sectioned, and submitted in F7-F8; complete section of mid gland anterior F9-F10; posterior F11-F12; complete section of upper third of gland, anterior F13-F14; posterior F15-F16; remainder of the posterior gland submitted in F17-F22; right seminal vesicle and vas deferens

[page 4 of 5]
F23; left seminal vesicle and vas deferens F24. After dissection, the remainder of the specimen is submitted complete in F25-F29.

Procedure

A. AA ROUTINE H&E X1 BLOCK
H&E X1
B. AA ROUTINE H&E X1 BLOCK
H&E X1
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1
F. AA ROUTINE H&E X1 BLOCK.1
H&E X1
F. AA ROUTINE H&E X1 BLOCK.2
H&E X1
F. AA ROUTINE H&E X1 BLOCK.3
H&E X1
F. AA ROUTINE H&E X1 BLOCK.4
H&E X1
F. AA ROUTINE H&E X1 BLOCK.5
H&E X1
F. AA ROUTINE H&E X1 BLOCK.6
H&E X1
F. AA ROUTINE H&E X1 BLOCK.7
H&E X1
F. AA ROUTINE H&E X1 BLOCK.8
H&E X1
F. AA ROUTINE H&E X1 BLOCK.9
H&E X1
F. AA ROUTINE H&E X1 BLOCK.10
H&E X1
F. AA ROUTINE H&E X1 BLOCK.11
H&E X1
F. AA ROUTINE H&E X1 BLOCK.12
H&E X1
F. AA ROUTINE H&E X1 BLOCK.13
H&E X1
F. AA ROUTINE H&E X1 BLOCK.14
H&E X1
F. AA ROUTINE H&E X1 BLOCK.15
H&E X1

[page 5 of 5]
F. AA ROUTINE H&E X1 BLOCK.16
H&E X1
F. AA ROUTINE H&E X1 BLOCK.17
H&E X1
F. AA ROUTINE H&E X1 BLOCK.18
H&E X1
F. AA ROUTINE H&E X1 BLOCK.19
H&E X1
F. AA ROUTINE H&E X1 BLOCK.20
H&E X1
F. AA ROUTINE H&E X1 BLOCK.21
H&E X1
F. AA ROUTINE H&E X1 BLOCK.22
H&E X1
F. AA ROUTINE H&E X1 BLOCK.23
H&E X1
F. AA ROUTINE H&E X1 BLOCK.24
H&E X1
F. AA ROUTINE H&E X1 BLOCK.25
H&E X1
F. AA ROUTINE H&E X1 BLOCK.26
H&E X1
F. AA ROUTINE H&E X1 BLOCK.27
H&E X1
F. AA ROUTINE H&E X1 BLOCK.28
H&E X1
F. AA ROUTINE H&E X1 BLOCK.29
H&E X1

Just/Sync/Not Sync Prime / Noted		/

Source: NCI Genomic Data Commons file fb9ce2bd-9e27-4da0-9ed7-ebe867daac59 (TCGA-J4-A83I.E3AFE230-AE22-4120-BC42-7FE78FCB06A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).